TCGA case TCGA-04-1654 — Ovarian Serous Cystadenocarcinoma (TCGA-OV)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Cystic, Mucinous and Serous Neoplasms; Primary site: Ovary; Tissue source site: Gynecologic Oncology Group. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/ff33db70-91d4-4dbb-a4fc-d81a128d0f32

Demographics
Sex at birth: female; Race: white; Age at index: 69 years; Vital status: Dead; Days to death: 1,451 days (4.0 years).

Diagnoses (2)
1. Serous cystadenocarcinoma, NOS (the primary disease): ICD-O-3 morphology code: 8441/3; ICD-10 code: C56.9; Tissue or organ of origin: Ovary; Site of resection or biopsy: Ovary; Laterality: Bilateral; Classification of tumor: primary; Age at diagnosis: 69.5 years (25,387 days); Year of diagnosis: 1999; Method of diagnosis: Cytology; FIGO stage: Stage IIIC; Tumor grade: G2; Prior treatment: No.
   Pathology details: Residual tumor measurement: 1-10 mm.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cisplatin; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 52 days; Number of cycles: 2; Treatment dose: 280 mg; Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Paclitaxel; Treatment intent type: Adjuvant; Days to treatment start: 31 days; Days to treatment end: 52 days; Number of cycles: 2; Treatment dose: 380 mg; Route of administration: Intraperitoneal / Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carboplatin + Paclitaxel; Initial disease status: Progressive Disease; Days to treatment start: 877 days (2.4 years).
   Recorded as not given: adjuvant Radiation Therapy, NOS.
2. Recurrence of diagnosis 1 (Serous cystadenocarcinoma, NOS). Age at diagnosis: 71.7 years (26,195 days); Days to diagnosis: 808 days (2.2 years); Prior treatment: Yes.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Recurrent Disease.
   Recorded as not given: Radiation Therapy, NOS, for recurrent disease.

Follow-up (3 entries)
- Day 808 (post initial treatment): Progression or recurrence: Yes; Days to recurrence: 808 days (2.2 years); Evidence of recurrence type: Convincing Image Source.
- ECOG performance status: 0; Timepoint: Prior to Adjuvant Therapy.
- Follow-up contact recording only the day: day 1,451.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-04-1654-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 1.2; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-04-1654-01A-02-BS2: Section location: Bottom; Percent tumor cells: 95; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 5.
  Slide TCGA-04-1654-01A-01-BS1: Section location: Top; Percent tumor cells: 90; Percent tumor nuclei: 99; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 5.
- Sample TCGA-04-1654-11A: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Longest dimension: 2; Intermediate dimension: 0.5; Shortest dimension: 0.4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Serous Cystadenocarcinoma; History neoadjuvant treatment: No; Performance status timing: Pre-Adjuvant Therapy; Method initial path diagnosis: Cytology (e.g. Peritoneal or pleural fluid).
- Drug treatment 1: Therapy regimen: Progression.
- Drug treatment 2, Route of administrations: Route of administration: IP; Route of administration: IV.
- Drug treatment 3: Pharmaceutical therapy drug name: Taxol; Therapy regimen: Progression.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,451 days; disease-specific survival: event status not recorded, 1,451 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 808 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; sample TCGA-04-1654-01): tumor purity 0.88, ploidy 1.94, whole-genome doublings 0 (call status: legacy_call).
